CCDI case PBCBIZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/e737c27d-64f1-4128-bf73-7db9878f55b4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 14.5 years (5,292 days).

Biospecimens (3 samples)
- Sample 0DN630: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN637: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DN63W: Tissue type: Tumor; Specimen type: Solid Tissue.
